Surgical pathology report (de-identified scan), TCGA case TCGA-98-A53H, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-A53H-01A (Primary Tumor).

[page 1 of 2]
Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

SURGICAL PATHOLOGY CASE:

Diagnosis

ICD-0-3

Carcinoma, squamous cell, NOS 8070/3

Site: lung, (R) upper lobe C34.1

hw
11/25/12

- A. Lymph node, level II, excision: - Negative for malignancy.
- B. Lymph node, level IV, excision: - Negative for malignancy.
- C. Lymph node, level X, excision: - Negative for malignancy.
- D. Lymph node, level IV, excision: - Negative for malignancy.
- E. Lymph node, level X, excision: Negative for malignancy.
- F. Lymph node, level X, excision:- Negative for malignancy.
- G. Lymph node, level X, excision: - Negative for malignancy.
- H. Lymph node, level X, excision:- Hyalinized granuloma. Negative for malignancy.
- I. Lymph node, level XI, excision: - Hyalinized granuloma with calcification. - Negative for malignancy.
- J. Lymph node, level VII, excision: - Calcified hyalinized granuloma. - No malignancy.
- K. Lymph node, level IX, excision: - Benign fibroadipose tissue. - No lymph node identified.
- L. Lymph node, level VIII, excision; - Negative for malignancy.
- M. Lymph node, level X, excision: - Negative for malignancy.
- N. Lymph node, level XI, excision: - Negative for malignancy.
- O. Bronchial margin, excision: - Negative for malignancy.
- P. Lung, right upper lobe, resection: - Squamous cell carcinoma, moderately differentiated. - Tumor measures 1.8 cm in greatest dimension. - Pleura is uninvolved by tumor. - Surgical margins, negative for malignancy.
- Q. Lymph node, level II, excision: - Negative for malignancy.

Pathologic stage: pT1a N0

Clinical Information: The patient is a year old female with a mediastinal lymph node and a right upper lobe nodule.

Frozen Section Diagnosis

- A: Lymph node, level 2, excision: - Negative for malignancy.
- B: Lymph node, level 4, excision: - Negative for malignancy.
- J: Lymph node, level 7, excision: - Hyalinized granuloma. - Negative for malignancy.
- O: Bronchial margin, excision: - Negative for malignancy.
- P: Right upper lobe, lung, lobectomy: - Squamous cell carcinoma.

Gross Description

The specimens are received in seventeen containers of formalin, labeled with the patients name and medical record number. The first container is additionally labeled "level 2 lymph node." Received is a cassette labeled with the patients name and A1, it is the remnant frozen section. Within the cassette is a piece of tan tissue measuring 0.6 x 0.2 x 0.4 cm, and it is submitted in its entirety in block A1.

The second container is additionally labeled "level 4 lymph node." Received is a cassette labeled with the patients name and B1. In the cassette are multiple fragments of tan-black tissue which measure in aggregate 3 x 1 x 0.2 cm. It is submitted in its entirety in cassette B1.

The third container is additionally labeled "level 10 lymph node." Received is a piece of tan-black tissue which measures 1 x 0.6 x 0.4 cm. It is submitted in its entirety in cassette C1.

The fourth container is additionally labeled "level 4 lymph node." Received is a piece of tan-black tissue which measures 0.8 x 0.4 x 0.6 cm. It is submitted in its entirety in cassette D1.

The fifth container is additionally labeled "level 10 lymph node." Received are two pieces of tan-black tissue which measure in aggregate 0.5 x 0.2 x 0.1 cm. It is submitted in its entirety in cassette E1.

The sixth container is additionally labeled "level 10 lymph node." Received are two fragments of black-tan tissue which measure in aggregate 0.4 x 0.2 x 0.3 cm. It is submitted in its entirety in cassette F1.

[page 2 of 2]
The seventh container is additionally labeled "level 10 lymph node." Received is a single piece of tan-brown tissue which measures 0.4 x 0.2 x 0.3 cm in diameter, It is submitted in its entirety in cassette G1.

The eighth container is additionally labeled "level 10 lymph node." Received are several pieces of tan-black tissue which measure in aggregate 0.7 x 0.9 x 0.4 cm. It is submitted in its entirety in cassette H1.

The ninth container is additionally labeled "level 11 lymph node." Received is a single fragment of tan-black tissue which measures in aggregate 0.5 x 0.2 x 0.4 cm. It is submitted in its entirety in cassette I1.

The tenth container is additionally labeled "level 7 lymph node - frozen." Received are multiple fragments of tissue which in aggregate measures 2.7 x 0.4 x 0.8 cm. Fragments representing the remnant frozen sections are submitted in cassette J1.

The **eleventh** container is additionally labeled "level 9 lymph node." Received is a single piece of tan tissue measuring 0.5 x 0.2 x 0.7 cm. It is submitted in its entirety in cassette K1. **The twelfth** container is additionally labeled "level 8 lymph node." Received is a single piece of tan-black tissue measuring 0.5 x 0.4 x 0.2 cm. It is submitted in its entirety in cassette L1. The **thirteenth** container is additionally labeled "level 10 lymph node." Received are several fragments of tan-black tissue which measure in aggregate 1 x 0.5 x 0.4 cm. The tissue is submitted in its entirety in cassette M1. The **fourteenth** container is additionally labeled "level 11 lymph node." Received are multiple fragments of tan-black tissue measuring in aggregate 0.6 x 0.5 x 0.3 cm. It is submitted in its entirety in cassette M1. The **fifteenth** container is additionally labeled "bronchial margin - frozen." Received is a single cassette labeled with the patients name and additionally O1. Within the cassette is a piece of tan-brown tissue which measures 1 x 0.5 x 0.4 cm. It is submitted in its entirety in cassette O1.

The sixteenth container is additionally labeled "right upper lobe - frozen." Received is a cassette labeled with the patients name and P1, representing the remnant frozen margin. This tissue is submitted in its entirety in cassette P1. Additionally in this container we have a piece of lung tissue which measures 15 x 9 x 2 cm. On the anti-hilar surface the lung has been previously opened prior to receiving. Inside of the lung parenchyma is a tan firm nodule which has previously been incised. The hilar surface of the lung is smooth and shiny. There is a staple line across the hilum and additionally across another aspect of the piece of lung. The staple line measures 6 cm. The anti-hilar surface of the pleura is smooth and shiny with minimal anthracosis. The parenchyma is serially sectioned and the yellow nodule is measured 1.8 cm in its greatest dimension. The remainder of the lung parenchyma is maroon, spongy with no evidence of any additional masses. A shave margin of the staple line is taken and submitted in cassette P2. Representative sections of the tumor are taken and submitted in cassettes P3 and P4. A representative section of the uninvolved lung parenchyma is taken in cassette P5. The seventeenth container is additionally labeled "level 2 lymph node." Received is a piece of tan-black tissue measuring 1 x 0.5 x 0.2 cm. It is submitted in its entirety in cassette Q1.

Block Summary

A1- Level 2 lymph node.
B1- Level 4 lymph node.
C1- Level 10 lymph node.
D1- Level 4 lymph node.
E1- Level 10 lymph node.
F1- Level 10 lymph node.
G1- Level 10 lymph node.
H1- Level 10 lymph node.
I1- Level 11 lymph node.

J1- Level 7 lymph node, frozen.
K1- Level 9 lymph node.
L1- Level 8 lymph node.
M1- Level 10 lymph node.
N1- Level 11 lymph node.
O1- Bronchial margin - frozen.
P1- Right upper lobe - frozen section remnant.
P2- Staple line shaved margin.
P3-P4 Representative sections of right upper lobe mass.
P5- Representative section of lung parenchyma.

Microscopic Description: A microscopic examination has been performed.

Source: NCI Genomic Data Commons file 4aee1d51-5abc-4d6c-81f9-2c4dc92f466c (TCGA-98-A53H.70F9038F-903B-4726-8DEB-CF4867136B9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).